Somatic mutation profile of tumor specimen 0DVCF3 from CCDI case PBCLDR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.9 years (3,978 days).
Specimen 0DVCF3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50600f1b-5af7-4701-8cda-fecb1f7ccaa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc692b89-ffe0-4dc9-a75a-c29385ee47c5

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOBR | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.329); catalogued as rs751288222; called by muse, mutect2, varscan2
- SLC22A1 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 125/340 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as rs532477464; called by muse, mutect2, varscan2
- TTN | c.2114T>C p.V705A (on ENST00000591111; = p.V659A on NM_003319.4) | Missense Mutation (SNP) | VAF 105/458 reads (23%) | PolyPhen probably damaging (0.99); catalogued as rs756066854; called by muse, varscan2
- PHF12 | c.1688G>T p.R563L | Missense Mutation (SNP) | VAF 158/646 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 22/640 reads (3%) | called by muse, mutect2
- TRPA1 | c.1195-74T>A | Intron (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
